Somatic mutation profile of tumor specimen TCGA-L9-A7SV-01A (aliquot TCGA-L9-A7SV-01A-11D-A397-08) from TCGA case TCGA-L9-A7SV, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.3 years (25,298 days).
Specimen TCGA-L9-A7SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6954da3-287b-4a5f-b4de-e690fb8ed425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A7SV-10A (Blood Derived Normal), aliquot TCGA-L9-A7SV-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44a776b7-0eb2-463c-ab1d-80c654278f56

The open-access MAF lists 1,766 somatic variants for this specimen: 1,284 protein-altering or splice-affecting, 427 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,109, Silent 427, Nonsense Mutation 103, Splice Site 31, Intron 27, Frame Shift Del 20, RNA 16, Splice Region 9, Frame Shift Ins 6, 5'UTR 4, 5'Flank 3, Nonstop Mutation 3.

Variants (750 of 1,766; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN1 | c.2923G>T p.E975* | Nonsense Mutation (SNP) | VAF 79/163 reads (48%) | catalogued as rs1555201480, COSV100751889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.471G>C p.M157I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100229429; called by muse, mutect2, varscan2
- A4GNT | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52630085; called by muse, mutect2, varscan2
- AADACL3 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1285047394, COSV100206879; called by muse, mutect2, varscan2
- AADACL4 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100879498; called by muse, mutect2
- ABCA12 | c.3221T>C p.M1074T (on ENST00000272895 / NM_173076.3; = p.M756T on NM_015657.3) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99791874; called by muse, mutect2, varscan2
- ABCA13 | c.15055T>A p.S5019T | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV101291430; called by muse, mutect2, varscan2
- ABCA5 | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs939544386, COSV101201278; called by muse, mutect2, varscan2
- ABCA8 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99286842; called by muse, mutect2, varscan2
- ABCA9 | c.3087G>T p.W1029C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV100383459; called by muse, mutect2, varscan2
- ABCB5 | c.3577-1G>C p.X1193_splice (on ENST00000404938 / NM_001163941.2; = p.X748_splice on NM_178559.6) | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99329522; called by muse, mutect2, varscan2
- ABCC1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as COSV100580313; called by muse, mutect2, varscan2
- ABCC2 | c.3520C>T p.R1174C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746497342, COSV64987502; called by muse, mutect2, varscan2
- ABCC3 | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99559773; called by muse, mutect2, varscan2
- ABLIM3 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV100448778, COSV58644797; called by muse, mutect2, varscan2
- ACE | c.1592T>A p.F531Y | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV99327685; called by muse, mutect2, varscan2
- ACHE | c.1044C>A p.N348K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.48); catalogued as COSV99574544; called by muse, mutect2, varscan2
- ACKR1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100929656; called by muse, varscan2
- ACSBG1 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV51903267, COSV99357652, COSV99357780; called by muse, mutect2
- ACSM1 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99533403; called by muse, mutect2, varscan2
- ACTN2 | c.2157C>A p.H719Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100856985; called by muse, mutect2, varscan2
- ACTRT2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201756456, COSV101007665; called by muse, mutect2, varscan2
- ADAM22 | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776432293, COSV99718225; called by muse, mutect2, varscan2
- ADAM23 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008736; called by muse, mutect2, varscan2
- ADAM7 | c.2264G>A p.*755= | Splice Region (SNP) | VAF 44/61 reads (72%) | catalogued as COSV99444316, COSV99445022; called by muse, mutect2, varscan2
- ADAMTS1 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV99536506; called by muse, mutect2, varscan2
- ADAMTS12 | c.1718+1G>T p.X573_splice | Splice Site (SNP) | VAF 143/204 reads (70%) | catalogued as rs779934275, COSV100711659; called by muse, mutect2, varscan2
- ADAMTS17 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99171574; called by muse, mutect2, varscan2
- ADAMTS17 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746864724, COSV99171576; called by muse, mutect2
- ADAMTS2 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV99283756; called by muse, mutect2, varscan2
- ADAMTS2 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV99283760; called by muse, mutect2, varscan2
- ADAMTS5 | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV53181108; called by muse, mutect2
- ADAMTS7 | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV101183248; called by muse, mutect2, varscan2
- ADCY10 | c.1662C>A p.F554L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100897078; called by muse, mutect2, varscan2
- ADCY6 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.358); catalogued as COSV100326891; called by muse, mutect2, varscan2
- ADGRA1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1330931525, COSV101192739; called by mutect2, varscan2
- ADGRA1 | c.1644C>A p.N548K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101192740; called by muse, mutect2, varscan2
- ADGRF1 | c.2084A>G p.Q695R | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99347592; called by muse, mutect2, varscan2
- ADGRF1 | c.2083C>A p.Q695K | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99347593; called by muse, mutect2, varscan2
- ADGRL2 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54664896, COSV99591429; called by muse, mutect2, varscan2
- ADGRL2 | c.905G>T p.W302L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408708856, COSV54697409; called by muse, mutect2, varscan2
- ADRA2A | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1403588144, COSV99701793; called by muse, mutect2, varscan2
- AFG1L | c.1445A>T p.*482Lext*7 | Nonstop Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs1241156155, COSV100934004; called by muse, mutect2, varscan2
- AFM | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99889210; called by muse, mutect2
- AGBL1 | c.1254G>T p.R418S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as rs1213789782, COSV101224185; called by muse, mutect2, varscan2
- AGO1 | c.1074G>C p.Q358H | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100940923; called by muse, mutect2, varscan2
- AGRN | c.3458A>T p.E1153V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101039060; called by muse, mutect2, varscan2
- AHNAK2 | c.2416C>A p.P806T | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs575899431, COSV100318876; called by muse, mutect2, varscan2
- AHSG | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99890349; called by muse, mutect2, varscan2
- AIM2 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 24/513 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV100931149; called by muse, mutect2
- AIMP1 | c.666A>T p.L222F | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100786212; called by muse, mutect2, varscan2
- AIMP1 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100786213; called by muse, mutect2, varscan2
- AK4 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100519995; called by muse, mutect2, varscan2
- AK5 | c.781C>A p.Q261K (on ENST00000354567 / NM_174858.3; = p.Q235K on NM_012093.4) | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV100643366; called by muse, mutect2, varscan2
- AKAP12 | c.1733G>A p.C578Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs150161531; called by muse, mutect2, varscan2
- AKAP13 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774584; called by muse, mutect2, varscan2
- AKAP6 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV55208042, COSV99804246; called by muse, mutect2, varscan2
- AKR1B15 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV101423406, COSV71151394; called by muse, mutect2, varscan2
- AKR1C2 | c.679T>C p.W227R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV101060537; called by muse, mutect2, varscan2
- ALB | c.1739A>T p.E580V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV55740891, COSV99892185; called by muse, mutect2, varscan2
- ALDH1L1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs775850788, COSV99856514, COSV99857490; called by muse, mutect2, varscan2
- ALMS1 | c.3737G>C p.G1246A | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.197); catalogued as COSV100043610; called by muse, mutect2, varscan2
- ALOX5 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs780844866, COSV100980189; called by muse, mutect2, varscan2
- ALPK2 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 91/206 reads (44%) | catalogued as COSV100864785, COSV64495148; called by muse, mutect2, varscan2
- AMER3 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100366878, COSV58466197; called by muse, mutect2, varscan2
- AMFR | c.972C>T p.A324= | Splice Region (SNP) | VAF 37/106 reads (35%) | catalogued as COSV99316213; called by muse, mutect2, varscan2
- ANAPC4 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100194233; called by muse, mutect2, varscan2
- ANGEL1 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99200481; called by muse, mutect2, varscan2
- ANGEL2 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100853994; called by muse, mutect2, varscan2
- ANK2 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100004094; called by muse, varscan2
- ANK2 | c.7369C>A p.P2457T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100004105; called by muse, mutect2, varscan2
- ANK3 | c.8062A>G p.T2688A | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV55070372; called by muse, mutect2, varscan2
- ANK3 | c.6522G>T p.R2174S | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99782212; called by muse, mutect2, varscan2
- ANKIB1 | c.2884G>T p.D962Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV99729901; called by muse, mutect2, varscan2
- ANKRD12 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100042049; called by muse, mutect2, varscan2
- ANKRD34A | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1553761083, COSV100041399; called by muse, mutect2, varscan2
- ANKZF1 | c.196del p.M66Wfs*35 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | catalogued as COSV55475336; called by mutect2, pindel, varscan2
- ANO1 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368534768, COSV100304450; called by muse, mutect2
- AOAH | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99333755; called by muse, mutect2, varscan2
- AP002512.3 | c.603G>T p.L201F | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0.105); catalogued as COSV54407864; called by muse, mutect2, varscan2
- AP1G1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250944; called by muse, mutect2, varscan2
- APOB | c.11180C>A p.A3727D | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV99267902; called by muse, mutect2, varscan2
- APOB | c.8338G>A p.G2780R | Missense Mutation (SNP) | VAF 132/193 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs781756323, COSV99267904; called by muse, mutect2, varscan2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- APOC4 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 78/140 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52991039; called by muse, mutect2, varscan2
- AQP12B | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs959286311, COSV101315851; called by muse, mutect2
- ARHGAP10 | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1297005922, COSV100331740; called by muse, mutect2, varscan2
- ARHGEF37 | c.1648G>T p.V550L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276991560, COSV100382324; called by muse, mutect2, varscan2
- ARMC5 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182126474, COSV99192819; called by muse, mutect2, varscan2
- ARMC5 | c.1998G>T p.R666= | Splice Region (SNP) | VAF 31/51 reads (61%) | catalogued as COSV99192820; called by muse, mutect2, varscan2
- ARMH3 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100228965; called by muse, mutect2, varscan2
- ARMT1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100939853; called by muse, mutect2, varscan2
- ASAP1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 123/231 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100727789; called by muse, mutect2, varscan2
- ASB17 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV99408063; called by muse, mutect2, varscan2
- ASIC2 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99861075; called by muse, mutect2, varscan2
- ASTN2 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1490973136, COSV100530235; called by muse, varscan2
- ASTN2 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV100530237; called by muse, varscan2
- ASXL3 | c.4537C>A p.P1513T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV99326459; called by muse, mutect2, varscan2
- ASXL3 | c.4538C>A p.P1513H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs749918007, COSV99326462; called by muse, mutect2, varscan2
- ATG2A | c.1393G>T p.G465W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101034782; called by muse, mutect2, varscan2
- ATP10D | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99906160; called by muse, mutect2, varscan2
- ATP1A3 | c.2582-2A>T p.X861_splice (on ENST00000545399 / NM_001256214.2; = p.X848_splice on NM_152296.5) | Splice Site (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100132533; called by muse, mutect2, varscan2
- ATP6V1H | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778818; called by muse, mutect2, varscan2
- ATP8B3 | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as rs1366832364, COSV100034940; called by muse, mutect2, varscan2
- ATP9B | c.1021G>T p.V341F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100304164; called by muse, mutect2, varscan2
- ATRNL1 | c.3190G>T p.G1064C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100372715; called by muse, mutect2, varscan2
- ATXN7L2 | c.800A>T p.Q267L | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100881366, COSV63993004; called by muse, mutect2, varscan2
- AURKB | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100298886; called by muse, mutect2, varscan2
- B3GNT6 | c.727C>A p.R243S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs374076293, COSV100845805; called by muse, mutect2, varscan2
- B4GALT3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV100157918; called by muse, mutect2, varscan2
- BACH2 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV100000868, COSV57586295; called by muse, mutect2, varscan2
- BAZ2B | c.145G>T p.G49* | Nonsense Mutation (SNP) | VAF 62/122 reads (51%) | catalogued as COSV100600976; called by muse, mutect2, varscan2
- BBS4 | c.354A>T p.K118N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs752934238, COSV99166533; called by muse, mutect2, varscan2
- BCL11B | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100595875; called by muse, mutect2, varscan2
- BCOR | c.2783G>T p.S928I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV100654077, COSV60714628; called by muse, mutect2, varscan2
- BEND7 | c.382A>T p.K128* | Nonsense Mutation (SNP) | VAF 57/118 reads (48%) | catalogued as COSV100347021; called by muse, mutect2, varscan2
- BICRAL | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100018453, COSV58404734; called by muse, mutect2, varscan2
- BMT2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV99774842; called by muse, mutect2, varscan2
- BNC1 | c.1688C>A p.S563* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as COSV100597469, COSV100597516; called by muse, mutect2, varscan2
- BOC | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1404105295, COSV99849338; called by muse, mutect2, varscan2
- BSN | c.4222C>A p.R1408S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs143474442, COSV99609730; called by muse, mutect2, varscan2
- BSN | c.6157G>C p.A2053P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99609733; called by muse, mutect2, varscan2
- BTBD8 | c.1106T>G p.M369R | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV100730465; called by muse, mutect2, varscan2
- BTN2A2 | c.1249T>A p.F417I | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100760592; called by muse, mutect2, varscan2
- C10orf90 | c.1877C>A p.T626K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757981077, COSV52954411, COSV99505031; called by muse, mutect2, varscan2
- C10orf90 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as rs756526430, COSV99504811; called by muse, mutect2, varscan2
- C10orf99 | c.33T>A p.C11* | Nonsense Mutation (SNP) | VAF 30/234 reads (13%) | catalogued as COSV100929367, COSV100929369; called by muse, mutect2, varscan2
- C16orf46 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs1378311053, COSV55152158; called by muse, mutect2, varscan2
- C1QL4 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.32); catalogued as COSV57742980, COSV99227013; called by muse, mutect2
- C1orf74 | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.629); catalogued as COSV99163015; called by muse, mutect2, varscan2
- C20orf194 | c.2916G>T p.M972I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV99331484; called by muse, mutect2, varscan2
- C3 | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV99837212; called by muse, mutect2, varscan2
- C9 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.39); catalogued as COSV99662523; called by muse, mutect2
- C9orf50 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100992350; called by muse, mutect2, varscan2
- CA9 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as rs746857543, COSV100253504, COSV61406222; called by muse, mutect2, varscan2
- CAB39 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.467); catalogued as COSV99300092; called by muse, mutect2, varscan2
- CACNA1E | c.6595G>T p.A2199S (on ENST00000367573 / NM_001205293.3; = p.A2156S on NM_000721.4) | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100705171; called by muse, mutect2, varscan2
- CACNA2D1 | c.3128C>T p.P1043L (on ENST00000356253 / NM_001366867.1; = p.P1031L on NM_000722.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100667067; called by muse, mutect2, varscan2
- CACNA2D1 | c.1736T>A p.I579N (on ENST00000356253 / NM_001366867.1; = p.I560N on NM_000722.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100667241; called by muse, mutect2, varscan2
- CACNG4 | c.768G>T p.R256S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV100047886; called by muse, mutect2, varscan2
- CACNG5 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99400810; called by muse, mutect2
- CALCA | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100524115; called by muse, mutect2, varscan2
- CALCR | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV100810845; called by muse, mutect2, varscan2
- CAMK2G | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99990300; called by muse, mutect2, varscan2
- CAMP | c.427C>T p.R143W (on ENST00000296435; = p.R140W on NM_004345.5) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs141472233; called by muse, mutect2, varscan2
- CAPN11 | c.2071G>C p.D691H | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV101291945, COSV67237656; called by muse, mutect2, varscan2
- CAPN6 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV100137059; called by muse, mutect2, varscan2
- CARMIL1 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV100278784; called by muse, mutect2, varscan2
- CARMIL2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV100576272; called by muse, mutect2, varscan2
- CBR1 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99289601; called by muse, mutect2, varscan2
- CCDC148 | c.793T>A p.W265R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99321389; called by muse, mutect2, varscan2
- CCDC171 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99901903; called by muse, mutect2, varscan2
- CCDC174 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs766201512, COSV100358708; called by muse, mutect2, varscan2
- CCDC24 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as COSV100746505; called by muse, mutect2, varscan2
- CCDC38 | c.305-2A>T p.X102_splice | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100717856; called by muse, mutect2, varscan2
- CCDC40 | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as COSV100884318; called by muse, mutect2
- CCDC66 | c.1925C>T p.S642F (on ENST00000394672 / NM_001353147.1; = p.S608F on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414331; called by muse, mutect2, varscan2
- CCDC74B | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100134728; called by muse, mutect2, varscan2
- CCDC87 | c.897del p.S300Rfs*36 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs1452616058; called by mutect2, pindel, varscan2
- CCKAR | c.805T>A p.C269S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55164336, COSV99810525; called by muse, mutect2, varscan2
- CCT4 | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101075379; called by muse, mutect2, varscan2
- CD247 | c.434T>A p.L145H (on ENST00000362089 / NM_198053.3; = p.L144H on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1250793718, COSV99612197; called by muse, mutect2, varscan2
- CD300C | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs979540838, COSV100423348, COSV58169569; called by muse, mutect2, varscan2
- CD36 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV99987869; called by muse, mutect2, varscan2
- CD40LG | c.409+1G>T p.X137_splice | Splice Site (SNP) | VAF 64/69 reads (93%) | catalogued as CS962407, CS971643, COSV101033557; called by muse, mutect2, varscan2
- CD44 | c.540C>A p.S180R | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99555997; called by muse, mutect2, varscan2
- CD6 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100533258; called by muse, mutect2, varscan2
- CD7 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486374; called by muse, mutect2, varscan2
- CD96 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51914237; called by muse, mutect2, varscan2
- CDC25B | c.328G>T p.G110C (on ENST00000245960 / NM_021873.3; = p.G96C on NM_004358.4) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488303200, COSV99848356; called by muse, mutect2, varscan2
- CDC40 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV100309567; called by muse, mutect2, varscan2
- CDCA7 | c.692C>A p.S231* (on ENST00000347703 / NM_145810.3; = p.S310* on NM_031942.5) | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100143754, COSV60719943; called by muse, mutect2, varscan2
- CDH12 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 257/338 reads (76%) | catalogued as COSV101203290; called by muse, mutect2, varscan2
- CDH20 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.273); catalogued as COSV99406491; called by muse, mutect2, varscan2
- CDH22 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952979, COSV64839727; called by muse, mutect2, varscan2
- CDH24 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1397739345, COSV99400296; called by muse, mutect2, varscan2
- CDK14 | c.1205G>C p.C402S (on ENST00000380050 / NM_001287135.2; = p.C384S on NM_012395.3) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.985); catalogued as COSV99726812; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs751853766, COSV100575730; called by muse, mutect2, varscan2
- CDRT4 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100381607; called by muse, mutect2
- CEACAM4 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs1050639825, COSV99701212; called by muse, mutect2, varscan2
- CELF2 | c.196G>T p.V66F (on ENST00000416382 / NM_001025077.3; = p.V73F on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100258299; called by muse, mutect2, varscan2
- CEP112 | c.2585G>T p.R862I (on ENST00000392769 / NM_001353127.1; = p.R118I on NM_001037325.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs1354325741, COSV100439461; called by muse, mutect2
- CEP170B | c.2453G>T p.G818V (on ENST00000453495; = p.G747V on NM_015005.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.183); catalogued as COSV101371603; called by muse, mutect2, varscan2
- CEP290 | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100469784; called by muse, mutect2, varscan2
- CETN1 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100511402; called by muse, mutect2, varscan2
- CFAP157 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100077084; called by muse, mutect2, varscan2
- CFAP54 | c.4834C>A p.H1612N | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100733320; called by muse, mutect2, varscan2
- CFAP58 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs762542201, COSV100459119, COSV57211406; called by muse, mutect2, varscan2
- CFAP58 | c.2317G>T p.A773S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV100866025; called by muse, mutect2, varscan2
- CFAP61 | c.2717G>T p.W906L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV99846585; called by muse, mutect2, varscan2
- CFAP91 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99847482; called by muse, mutect2
- CFAP91 | c.1057G>T p.G353W | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99847483; called by muse, mutect2
- CFAP91 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as rs1177588639, COSV99847485; called by muse, mutect2, varscan2
- CFHR5 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 35/50 reads (70%) | catalogued as COSV56823039; called by muse, mutect2, varscan2
- CGB3 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1441911174, COSV100642236; called by muse, mutect2, varscan2
- CHD5 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52413051, COSV99314937; called by muse, mutect2, varscan2
- CHGB | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100973096; called by muse, mutect2
- CHL1 | c.2107C>G p.H703D (on ENST00000397491 / NM_001253387.1; = p.H719D on NM_006614.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99852268; called by muse, mutect2, varscan2
- CHL1 | c.3156G>A p.W1052* (on ENST00000397491 / NM_001253387.1; = p.W1068* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as rs1427979253, COSV56590287, COSV99852269; called by muse, mutect2, varscan2
- CHRD | c.2279C>A p.P760H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369623177, COSV99200765; called by muse, mutect2, varscan2
- CHRM2 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57769127, COSV57775493; called by muse, mutect2, varscan2
- CHTOP | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 124/157 reads (79%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.662); catalogued as rs759719295, COSV64155636; called by muse, mutect2, varscan2
- CLCN7 | c.536G>T p.W179L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as CM034390, COSV99247616; called by muse, mutect2, varscan2
- CLDN8 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99730003; called by muse, mutect2, varscan2
- CLPTM1 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV100493947; called by muse, mutect2, varscan2
- CLSTN2 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV101515918, COSV71724362; called by muse, mutect2
- CLUAP1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV100489793; called by muse, mutect2, varscan2
- CMTR2 | c.2194A>T p.K732* | Nonsense Mutation (SNP) | VAF 17/21 reads (81%) | catalogued as COSV100579339; called by muse, mutect2, varscan2
- CNBD1 | c.1230A>T p.Q410H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV101582317; called by muse, mutect2, varscan2
- CNGA2 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as rs1240874459, COSV100323932; called by muse, mutect2, varscan2
- CNIH3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV99686235; called by muse, mutect2, varscan2
- CNKSR3 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101401403; called by muse, mutect2, varscan2
- CNPPD1 | c.458dup p.V154Cfs*24 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | catalogued as rs1402381139; called by mutect2, pindel, varscan2
- CNTFR | c.457G>T p.V153F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV100667621; called by muse, mutect2, varscan2
- CNTN1 | c.2594C>A p.S865* | Nonsense Mutation (SNP) | VAF 66/208 reads (32%) | catalogued as COSV100751888, COSV61647110; called by muse, mutect2, varscan2
- CNTN3 | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99723320, COSV99726010; called by muse, mutect2, varscan2
- CNTN4 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100639713; called by muse, mutect2, varscan2
- CNTN4 | c.2738C>A p.S913* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100639714, COSV61881121; called by muse, mutect2, varscan2
- CNTNAP1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99226976; called by muse, mutect2, varscan2
- CNTNAP4 | c.300T>A p.Y100* | Nonsense Mutation (SNP) | VAF 47/67 reads (70%) | catalogued as rs1290256588, COSV100273259; called by muse, mutect2, varscan2
- CNTNAP4 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100273263, COSV56679370; called by muse, mutect2, varscan2
- CNTNAP5 | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101444192; called by muse, mutect2
- COBLL1 | c.3614A>C p.*1205Sext*19 (on ENST00000392717; = p.*1167Sext*19 on NM_014900.5) | Nonstop Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99528657; called by muse, mutect2, varscan2
- COL11A1 | c.4519-1G>T p.X1507_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100617974; called by muse, mutect2, varscan2
- COL11A1 | c.3716A>G p.Q1239R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100617975; called by muse, mutect2, varscan2
- COL11A1 | c.1999-1G>T p.X667_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as COSV62172611, COSV62179077, COSV62198366; called by muse, mutect2, varscan2
- COL11A1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100617976; called by muse, mutect2, varscan2
- COL14A1 | c.4432C>A p.Q1478K | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as rs189042874; called by muse, varscan2
- COL14A1 | c.5125C>A p.Q1709K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.696); catalogued as COSV99920598; called by muse, varscan2
- COL15A1 | c.3158G>C p.G1053A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV66651203; called by muse, mutect2, varscan2
- COL20A1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs1415029759, COSV100491414; called by muse, mutect2, varscan2
- COL22A1 | c.1978G>T p.G660* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100280677; called by muse, mutect2, varscan2
- COL22A1 | c.1245+1G>C p.X415_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV57367402; called by muse, mutect2
- COL4A6 | c.1184-1G>T p.X395_splice | Splice Site (SNP) | VAF 42/45 reads (93%) | catalogued as rs1207614022, COSV100564995; called by muse, mutect2, varscan2
- COL5A2 | c.1609G>C p.G537R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880777; called by muse, mutect2, varscan2
- COL5A3 | c.3556G>T p.E1186* | Nonsense Mutation (SNP) | VAF 48/66 reads (73%) | catalogued as rs1472878028, COSV99319733; called by muse, mutect2, varscan2
- COL6A1 | c.2774G>T p.R925L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV100720456; called by muse, mutect2, varscan2
- COL6A3 | c.4616G>T p.G1539V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99801234; called by muse, mutect2, varscan2
- COL6A6 | c.6024C>A p.D2008E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100650905; called by muse, mutect2, varscan2
- COPA | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99616742; called by muse, mutect2, varscan2
- CPAMD8 | c.1792C>T p.P598S (on ENST00000651564; = p.P551S on NM_015692.5) | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as rs1400124025, COSV99359787; called by muse, mutect2, varscan2
- CPLX2 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1445092611; called by muse, mutect2
- CPN1 | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100962725, COSV64942900; called by muse, mutect2, varscan2
- CPQ | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV99614560; called by muse, mutect2, varscan2
- CPS1 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99244032; called by muse, mutect2, varscan2
- CPXM2 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV53870696, COSV99582694; called by muse, mutect2, varscan2
- CR1 | c.4885C>A p.H1629N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.076); catalogued as rs1164800111, COSV100887540, COSV65461618; called by muse, mutect2, varscan2
- CRACD | c.3076G>T p.G1026* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1465262694, COSV99949987; called by muse, mutect2, varscan2
- CRB1 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66349561; called by muse, mutect2, varscan2
- CREB3L3 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99314484; called by muse, mutect2, varscan2
- CRH | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99396314; called by muse, mutect2, varscan2
- CRISP2 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100189226; called by muse, mutect2, varscan2
- CRISP2 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100189227, COSV59256387; called by muse, mutect2, varscan2
- CSMD1 | c.6437C>A p.P2146H (on ENST00000520002; = p.P2145H on NM_033225.6) | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373453393, COSV100153411, COSV59321447; called by mutect2, varscan2
- CSMD1 | c.4927C>A p.P1643T (on ENST00000520002; = p.P1642T on NM_033225.6) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1253115479, COSV100153413; called by muse, mutect2, varscan2
- CSMD3 | c.9609C>A p.Y3203* (on ENST00000297405 / NM_001363185.1; = p.Y3034* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 61/157 reads (39%) | catalogued as COSV99846864; called by muse, mutect2, varscan2
- CSMD3 | c.9281G>T p.R3094I (on ENST00000297405 / NM_001363185.1; = p.R2925I on NM_052900.3) | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52307000; called by muse, mutect2, varscan2
- CSMD3 | c.5461C>A p.P1821T (on ENST00000297405 / NM_001363185.1; = p.P1717T on NM_052900.3) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.314); catalogued as COSV99846867; called by muse, mutect2, varscan2
- CSMD3 | c.594C>A p.D198E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99846872; called by muse, mutect2, varscan2
- CSPG4 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs374349137; called by muse, mutect2, varscan2
- CSPP1 | c.2668A>G p.I890V (on ENST00000676605; = p.I849V on NM_024790.6) | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs932817255, COSV51580462; called by muse, mutect2, varscan2
- CST5 | c.409T>A p.Y137N | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV100489740; called by muse, mutect2, varscan2
- CSTF3 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as rs1309471424, COSV100124328; called by muse, mutect2, varscan2
- CTCFL | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754194450, COSV54772741; called by muse, mutect2, varscan2
- CTNNA2 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777032066, COSV63569988, COSV63590877; called by muse, mutect2, varscan2
- CTNNA3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101051515; called by muse, mutect2, varscan2
- CTR9 | c.3096-2A>T p.X1032_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100797526; called by muse, mutect2, varscan2
- CTSG | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99361684; called by muse, varscan2
- CTTNBP2 | c.4823G>A p.R1608K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99354810; called by muse, mutect2, varscan2
- CUBN | c.2273A>T p.Q758L | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100913489; called by muse, mutect2, varscan2
- CUX2 | c.4310C>A p.P1437H | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV99920693; called by muse, mutect2, varscan2
- CXCL10 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.213); catalogued as rs1299744355, COSV100134136; called by muse, mutect2, varscan2
- CXCR2 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100579075, COSV100579125; called by muse, mutect2, varscan2
- CYBB | c.72C>A p.F24L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as COSV101059818; called by muse, mutect2, varscan2
- CYLC2 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872579; called by muse, mutect2, varscan2
- CYP4A11 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.109); catalogued as COSV100152627; called by muse, mutect2, varscan2
- CYYR1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.567); catalogued as rs1470127181, COSV54827387; called by muse, mutect2, varscan2
- DAAM2 | c.1252C>G p.P418A | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99226931; called by muse, mutect2, varscan2
- DACH1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1428580611, COSV100499153, COSV57496016; called by muse, mutect2, varscan2
- DCAF12L1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100948381, COSV100948441; called by muse, mutect2, varscan2
- DCAF12L2 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758828, COSV63580143; called by muse, mutect2, varscan2
- DCAF4L1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as COSV100295985; called by muse, mutect2, varscan2
- DCAF4L2 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368602131, COSV100151277; called by muse, mutect2, varscan2
- DCAF7 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV100177756, COSV60407841; called by muse, mutect2
- DCC | c.1317G>T p.L439F | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59127363, COSV59138404; called by muse, mutect2, varscan2
- DCLK1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99712930; called by muse, mutect2, varscan2
- DCTN3 | c.412-4A>G | Splice Region (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99427042; called by muse, mutect2, varscan2
- DCUN1D1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV99490062; called by muse, mutect2, varscan2
- DDX23 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339962; called by muse, mutect2, varscan2
- DEFA4 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99857767; called by muse, mutect2, varscan2
- DGKB | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1351292100, COSV99343196; called by muse, mutect2, varscan2
- DHCR24 | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100987844; called by muse, mutect2
- DHRS2 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99160279; called by muse, mutect2, varscan2
- DIP2B | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99999323; called by muse, mutect2, varscan2
- DISP3 | c.1571T>A p.F524Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609909; called by muse, mutect2, varscan2
- DKK1 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1312432362, COSV100906582; called by muse, mutect2, varscan2
- DLGAP4 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100211587; called by muse, mutect2, varscan2
- DLX6 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99142506; called by muse, mutect2
- DMBT1 | c.1756A>T p.S586C | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV100354048; called by muse, mutect2, varscan2
- DMGDH | c.1565A>G p.Y522C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs760435362, COSV99669497; called by muse, mutect2, varscan2
- DMXL1 | c.7375G>T p.D2459Y | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100224927; called by muse, mutect2, varscan2
- DNA2 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100622808; called by muse, mutect2
- DNAH1 | c.5632G>T p.A1878S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV101327014; called by muse, mutect2
- DNAH17 | c.6920G>T p.R2307L | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs754142297, COSV101103403; called by muse, mutect2, varscan2
- DNAH2 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99318567; called by muse, mutect2
- DNAH5 | c.7888-2A>T p.X2630_splice | Splice Site (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99453934; called by muse, mutect2
- DNAH5 | c.3443G>T p.W1148L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99453941; called by muse, mutect2, varscan2
- DNAH5 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54213926, COSV99453943; called by muse, mutect2, varscan2
- DNAH9 | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV52339006, COSV99307955; called by muse, mutect2, varscan2
- DNAI1 | c.1543G>T p.G515C | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM011938, COSV99647140; called by muse, mutect2, varscan2
- DNAI2 | c.1814C>G p.A605G | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as COSV100210057; called by muse, mutect2, varscan2
- DNAI4 | c.1776G>T p.Q592H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100925341; called by muse, mutect2, varscan2
- DNAJC13 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99608068; called by muse, mutect2, varscan2
- DNAJC13 | c.4993A>T p.K1665* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1431326559, COSV53444955; called by muse, mutect2, varscan2
- DNAJC21 | c.1598A>G p.H533R | Missense Mutation (SNP) | VAF 309/419 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as rs750856412, COSV100331596; called by muse, mutect2, varscan2
- DNER | c.2102+1G>T p.X701_splice | Splice Site (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100519984; called by muse, mutect2, varscan2
- DNER | c.2102G>T p.R701M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100519986; called by muse, mutect2, varscan2
- DNM1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100360312; called by muse, mutect2, varscan2
- DNM1 | c.1769A>C p.N590T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV100360313; called by muse, mutect2, varscan2
- DOCK2 | c.692T>A p.V231E | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99915207; called by muse, mutect2, varscan2
- DOCK2 | c.2557T>A p.C853S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99915210; called by muse, mutect2, varscan2
- DPYSL4 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.828); catalogued as rs763656593, COSV100634043; called by muse, mutect2, varscan2
- DSC3 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844720; called by muse, mutect2, varscan2
- DSCAM | c.5816G>A p.R1939H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV68020286; called by muse, mutect2, varscan2
- DSCAM | c.1850G>C p.C617S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101261471; called by muse, mutect2, varscan2
- DSCAM | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV101261472; called by muse, mutect2, varscan2
- DSEL | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV100026080; called by muse, mutect2, varscan2
- DSG4 | c.2270G>T p.R757M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100356403; called by muse, mutect2, varscan2
- DST | c.8363G>T p.C2788F | Missense Mutation (SNP) | VAF 151/259 reads (58%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99759739; called by muse, mutect2, varscan2
- DST | c.6091G>T p.D2031Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV99759740; called by muse, mutect2, varscan2
- DTNA | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315189; called by muse, mutect2, varscan2
- DTNA | c.1684C>A p.R562S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV99315197; called by muse, mutect2, varscan2
- DYDC1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1358292960, COSV55473683, COSV99758193; called by muse, mutect2, varscan2
- DYNC1I1 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368505837; called by muse, mutect2, varscan2
- DYNC2I2 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.043); catalogued as COSV65549690; called by muse, mutect2, varscan2
- DYSF | c.5127T>A p.H1709Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV50268039, COSV99250283; called by muse, mutect2, varscan2
- DZIP1L | c.1928G>C p.R643P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV100551697, COSV59522516; called by muse, mutect2, varscan2
- EBF1 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100566555; called by muse, mutect2, varscan2
- EFCAB7 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100937622; called by muse, mutect2, varscan2
- EHBP1 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376589251, COSV99861823; called by muse, mutect2, varscan2
- EHMT1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100604221; called by muse, mutect2, varscan2
- EHMT2 | c.1909G>T p.V637F | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs1350938013, COSV100977242; called by muse, mutect2, varscan2
- EID1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs750264190, COSV100195304; called by muse, mutect2, varscan2
- ELOVL2 | c.341A>T p.K114M | Missense Mutation (SNP) | VAF 106/116 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100676072; called by muse, mutect2, varscan2
- ELP1 | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101010486; called by muse, mutect2, varscan2
- ELP6 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.167); catalogued as COSV99948225; called by muse, mutect2, varscan2
- ELSPBP1 | c.414T>A p.N138K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100353770; called by muse, mutect2, varscan2
- EMILIN2 | c.217A>T p.N73Y | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV99598886; called by muse, mutect2, varscan2
- ENPP1 | c.2555A>T p.D852V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs772387213, COSV100719641; called by muse, mutect2, varscan2
- ENY2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100373921; called by muse, mutect2, varscan2
- EPB41L2 | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as rs150873575, COSV100441372; called by muse, mutect2, varscan2
- EPHA4 | c.1937G>T p.R646I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917443; called by muse, mutect2, varscan2
- EPHA6 | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101065369, COSV67576788; called by muse, mutect2, varscan2
- EPHB1 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101214342; called by muse, mutect2, varscan2
- EPHB1 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); catalogued as COSV101214344; called by muse, mutect2
- EPHB4 | c.391A>G p.M131V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.76); catalogued as COSV100639645; called by muse, mutect2, varscan2
- EPHB6 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772331271, COSV100844405, COSV63891302; called by muse, varscan2
- ERBB4 | c.2151G>T p.E717D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV99632250; called by muse, mutect2, varscan2
- ERC2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV99889587; called by muse, mutect2, varscan2
- ERMN | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV101263068, COSV68075681; called by muse, mutect2, varscan2
- ERMN | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV101263019; called by muse, mutect2, varscan2
- ESYT2 | c.1196G>C p.G399A (on ENST00000613624; = p.G323A on NM_020728.3) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as COSV99277238; called by muse, mutect2, varscan2
- EVPL | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101648800; called by muse, mutect2, varscan2
- EXOC6 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592483; called by muse, mutect2, varscan2
- EXOC6B | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as COSV99726326; called by muse, mutect2, varscan2
- EXOSC2 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100964274; called by muse, mutect2, varscan2
- EYA4 | c.1862A>T p.N621I (on ENST00000531901 / NM_001301013.1; = p.N615I on NM_004100.5) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100766323; called by muse, mutect2, varscan2
- EZHIP | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.196); catalogued as COSV100539897; called by muse, mutect2
- F11 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99250920; called by muse, mutect2, varscan2
- FAM111A | c.1775G>T p.W592L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs770245385, COSV100659450; called by muse, mutect2, varscan2
- FAM135B | c.157+1G>T p.X53_splice | Splice Site (SNP) | VAF 39/77 reads (51%) | catalogued as rs1469910623, COSV99358103; called by muse, varscan2
- FAM135B | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50546395; called by muse, varscan2
- FAM168B | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as COSV101112262; called by muse, mutect2, varscan2
- FAM171B | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59010781; called by muse, mutect2, varscan2
- FAM47A | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as COSV60496593; called by muse, mutect2, varscan2
- FAM47B | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 57/159 reads (36%) | catalogued as COSV100264617, COSV100264620; called by muse, mutect2, varscan2
- FAM47C | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100792934; called by muse, mutect2, varscan2
- FAM71B | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 168/215 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100262310; called by muse, mutect2, varscan2
- FAM71F2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1393858272, COSV101100733; called by muse, mutect2, varscan2
- FAM83C | c.1659C>A p.S553R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV100981702; called by muse, mutect2, varscan2
- FAM83C | c.1262C>A p.P421Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV100981703; called by muse, mutect2
- FAM83D | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770889253; called by muse, mutect2, varscan2
- FAM83F | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100329085; called by muse, mutect2, varscan2
- FAM91A1 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 84/493 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100593783; called by muse, mutect2
- FANK1 | c.534G>C p.K178N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904816; called by muse, mutect2, varscan2
- FASLG | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV60680202; called by muse, mutect2, varscan2
- FASN | c.7217A>G p.K2406R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100148305; called by muse, mutect2, varscan2
- FBN2 | c.7151G>T p.G2384V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs146260199, COSV52520307; called by muse, mutect2, varscan2
- FBXL18 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs774712437, COSV101212110; called by muse, mutect2, varscan2
- FCAR | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs762426689, COSV100629194, COSV62030693; called by muse, mutect2
- FCHSD1 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1231902903, COSV99781516; called by muse, mutect2, varscan2
- FCN2 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99391437; called by muse, mutect2
- FCRLA | c.518C>T p.P173L (on ENST00000367959; = p.P150L on NM_032738.4) | Missense Mutation (SNP) | VAF 90/109 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99375746, COSV99376599; called by muse, mutect2
- FCRLA | c.520G>T p.G174C (on ENST00000367959; = p.G151C on NM_032738.4) | Missense Mutation (SNP) | VAF 87/106 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99376606; called by muse, mutect2
- FER | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.621); catalogued as COSV99813898; called by muse, mutect2, varscan2
- FER | c.2134G>T p.G712* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99813902; called by muse, mutect2, varscan2
- FERMT1 | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99452110; called by muse, mutect2, varscan2
- FFAR3 | c.91del p.L31Sfs*27 | Frame Shift Del (DEL) | VAF 31/80 reads (39%) | catalogued as COSV59909196, COSV59909320; called by mutect2, varscan2
- FLACC1 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV99630859; called by muse, mutect2, varscan2
- FLG | c.8561C>T p.S2854L | Missense Mutation (SNP) | VAF 122/4443 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV64245998; called by muse, mutect2
- FLG | c.8560T>A p.S2854T | Missense Mutation (SNP) | VAF 122/4436 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV100911843, COSV100912163; called by muse, mutect2
- FLG | c.4610C>A p.P1537H | Missense Mutation (SNP) | VAF 943/1412 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100912167; called by muse, mutect2, varscan2
- FLNB | c.3899-1G>T p.X1300_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99914724; called by muse, mutect2, varscan2
- FMOD | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100724629; called by muse, mutect2, varscan2
- FMR1NB | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.774); catalogued as COSV100975543, COSV100975617; called by muse, mutect2, varscan2
- FNBP1 | c.1595T>C p.M532T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1287770292, COSV100852791; called by muse, mutect2, varscan2
- FNDC1 | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV51939371, COSV99796761; called by muse, mutect2, varscan2
- FNIP1 | c.2420A>T p.E807V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100330596; called by muse, mutect2, varscan2
- FOCAD | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.888); catalogued as rs958739496, COSV100620684; called by muse, mutect2, varscan2
- FSD1 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs776233464, COSV99697026; called by muse, mutect2, varscan2
- FSIP2 | c.18632A>T p.K6211I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100556409; called by muse, mutect2, varscan2
- FSTL5 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100060748; called by muse, mutect2, varscan2
- FUBP3 | c.1484G>C p.W495S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100156311; called by muse, mutect2, varscan2
- FXYD5 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100732758; called by muse, mutect2, varscan2
- FZD1 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.593); catalogued as rs1223388464, COSV99842737; called by muse, mutect2, varscan2
- FZD10 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57473678, COSV99969588; called by muse, mutect2, varscan2
- GABRA1 | c.1291T>G p.F431V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196268; called by muse, mutect2, varscan2
- GABRA6 | c.775del p.Q259Rfs*23 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as COSV50892822; called by mutect2, pindel, varscan2
- GABRG2 | c.1397C>A p.T466K (on ENST00000361925 / NM_001375343.1; = p.T426K on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100729839; called by muse, mutect2, varscan2
- GAL3ST4 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV100385636, COSV57585174; called by muse, mutect2, varscan2
- GALNT15 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV100328004; called by muse, mutect2, varscan2
- GALNT3 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 48/78 reads (62%) | catalogued as COSV101205009; called by muse, mutect2, varscan2
- GAN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV101634020, COSV101634028; called by muse, mutect2, varscan2
- GAREM1 | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV99331344; called by muse, mutect2, varscan2
- GAREM1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99331346; called by muse, mutect2, varscan2
- GBA | c.435A>T p.K145N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV100516460; called by muse, mutect2, varscan2
- GBP1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs764543303, COSV100976303; called by muse, mutect2, varscan2
- GCC1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100365569; called by muse, mutect2, varscan2
- GCM1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199724971, COSV99452646; called by muse, mutect2, varscan2
- GCN1 | c.3169-1G>T p.X1057_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100325940; called by muse, mutect2, varscan2
- GCN1 | c.2557G>T p.G853W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1274656524, COSV100325943; called by muse, mutect2, varscan2
- GLI2 | c.888C>A p.Y296* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100082758, COSV100084250; called by muse, mutect2, varscan2
- GLI3 | c.4646C>A p.A1549E | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV101230030, COSV67887884; called by muse, mutect2, varscan2
- GLI3 | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101230031; called by muse, mutect2, varscan2
- GLI3 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101230032; called by muse, mutect2, varscan2
- GLUD2 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100047007, COSV100047088; called by muse, mutect2, varscan2
- GP2 | c.1493G>T p.G498V (on ENST00000381362 / NM_001007240.3; = p.G495V on NM_001502.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100221647; called by muse, mutect2, varscan2
- GPN2 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs1449309419, COSV100658912; called by muse, mutect2, varscan2
- GPNMB | c.1627G>T p.V543F (on ENST00000381990 / NM_001005340.2; = p.V531F on NM_002510.3) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV99326820; called by muse, mutect2, varscan2
- GPR148 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV99998732; called by muse, mutect2, varscan2
- GPR152 | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100351660; called by muse, mutect2, varscan2
- GPR63 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV100013555; called by muse, mutect2, varscan2
- GPRIN2 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs781859727, COSV100966471; called by muse, mutect2
- GPX5 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101297285, COSV69079458; called by muse, mutect2, varscan2
- GRIA4 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 90/99 reads (91%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.864); catalogued as COSV99234361; called by muse, mutect2, varscan2
- GRIK4 | c.1420G>C p.G474R | Missense Mutation (SNP) | VAF 75/92 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483753; called by muse, mutect2, varscan2
- GRIN2A | c.3751G>T p.D1251Y | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM138251, COSV100410982; called by muse, mutect2, varscan2
- GRIN3A | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100701812; called by muse, mutect2, varscan2
- GRM2 | c.2446A>G p.I816V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.639); catalogued as COSV99623144; called by muse, mutect2, varscan2
- GRM7 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1365868608, COSV100738413; called by muse, mutect2, varscan2
- GSTA3 | c.669A>T p.*223Yext*1 | Nonstop Mutation (SNP) | VAF 66/179 reads (37%) | catalogued as rs1310459667, COSV99274657; called by muse, mutect2, varscan2
- GTF3A | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100820214; called by muse, mutect2, varscan2
- GUCY2D | c.2479T>A p.Y827N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644262; called by muse, mutect2, varscan2
- H1-7 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.488); catalogued as COSV100622260; called by muse, mutect2, varscan2
- HACD1 | c.566G>T p.S189I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100778515; called by muse, mutect2, varscan2
- HAND2 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100854241, COSV64017802; called by muse, mutect2, varscan2
- HAS2 | c.1040G>T p.W347L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100392180; called by muse, mutect2, varscan2
- HAUS6 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100998168; called by muse, mutect2, varscan2
- HCAR2 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100186640; called by muse, mutect2, varscan2
- HCN1 | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100302188; called by muse, mutect2
- HCN1 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1383711113, COSV100302190, COSV57535212; called by muse, varscan2
- HDAC9 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101287407; called by muse, mutect2
- HDC | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV51070172, COSV99984316; called by muse, mutect2, varscan2
- HEATR1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781187454, COSV100857792; called by muse, mutect2, varscan2
- HEATR5B | c.1333+1G>T p.X445_splice | Splice Site (SNP) | VAF 21/143 reads (15%) | catalogued as COSV99250193; called by muse, mutect2, varscan2
- HELT | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as COSV100133001; called by muse, mutect2, varscan2
- HEMGN | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99412513; called by muse, mutect2, varscan2
- HEPACAM | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100005919, COSV53429362; called by muse, mutect2, varscan2
- HERC1 | c.12005G>T p.W4002L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101496886; called by muse, mutect2, varscan2
- HGFAC | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894948926, COSV101237785, COSV66976725; called by muse, mutect2, varscan2
- HHIPL2 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100597094; called by muse, mutect2, varscan2
- HMCN1 | c.7538G>T p.W2513L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54913767; called by muse, mutect2, varscan2
- HMG20A | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs1389363722, COSV100287945; called by muse, mutect2, varscan2
- HNF1B | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); catalogued as rs1442869406; called by muse, mutect2, varscan2
- HNRNPD | c.964G>T p.G322C (on ENST00000313899 / NM_031370.3; = p.G303C on NM_031369.2) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100003070; called by muse, mutect2, varscan2
- HPCA | c.88T>A p.W30R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100992204; called by muse, mutect2, varscan2
- HPS4 | c.717G>C p.L239F | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV100404679; called by muse, mutect2, varscan2
- HPSE2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 77/133 reads (58%) | catalogued as COSV100986251; called by muse, mutect2, varscan2
- HS3ST4 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263066283, COSV100502917; called by muse, mutect2, varscan2
- HSPA4 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100507742, COSV100507867; called by muse, mutect2, varscan2
- HSPG2 | c.7006C>T p.P2336S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as rs745663099, COSV101021192, COSV65970257; called by muse, mutect2, varscan2
- HTN1 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV55895182, COSV99887588; called by muse, mutect2, varscan2
- HUWE1 | c.10307A>T p.N3436I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99474115; called by muse, mutect2, varscan2
- IFNA1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV99439975; called by muse, mutect2, varscan2
- IFNA1 | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs1339698516, COSV99439981; called by muse, mutect2, varscan2
- IFNA8 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs906640565, COSV101206938; called by muse, mutect2, varscan2
- IFNAR1 | c.1637G>T p.S546I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV99531821; called by muse, mutect2, varscan2
- IFNE | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58640202; called by muse, mutect2, varscan2
- IFT172 | c.2671C>A p.L891M | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV99563277; called by muse, mutect2, varscan2
- IGF2BP2 | c.1361C>A p.A454E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); catalogued as rs759073124, COSV100649503, COSV60485789; called by muse, mutect2, varscan2
- IGHV3-53 | c.215G>C p.S72T | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs781938806; called by muse, varscan2
- IGKV1-16 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as rs1281088502; called by muse, mutect2, varscan2
- IGSF1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as rs756120260, COSV100812299; called by muse, mutect2, varscan2
- IGSF9B | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100318380; called by muse, mutect2, varscan2
- IKBIP | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV100689782, COSV100689884; called by muse, mutect2, varscan2
- IKBKE | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100898381, COSV65625753; called by muse, mutect2, varscan2
- IL10RA | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99923267; called by muse, mutect2, varscan2
- IL16 | c.3035C>A p.A1012D (on ENST00000302987 / NM_172217.5; = p.A311D on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100268108; called by muse, mutect2, varscan2
- IL17RD | c.1176C>A p.D392E | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578059; called by muse, mutect2, varscan2
- IL1B | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99642020; called by muse, mutect2, varscan2
- IL1RL1 | c.1144G>T p.V382F | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99294502; called by muse, mutect2, varscan2
- IL21R | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs1323112773, COSV100560579; called by muse, mutect2, varscan2
- IL7R | c.669T>A p.S223R | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100286632, COSV57406284; called by muse, mutect2, varscan2
- IL7R | c.895A>T p.N299Y | Missense Mutation (SNP) | VAF 137/191 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100286634; called by muse, mutect2, varscan2
- IMPG1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as COSV100886647; called by muse, mutect2, varscan2
- IMPG2 | c.3603G>C p.Q1201H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99516455; called by muse, mutect2, varscan2
- INCENP | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99611513; called by muse, mutect2, varscan2
- INHA | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99217446; called by muse, mutect2, varscan2
- INPPL1 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99996626; called by muse, mutect2, varscan2
- INTS3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 39/685 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59680305; called by muse, mutect2
- INTU | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081378; called by muse, mutect2, varscan2
- IRS4 | c.3159G>T p.E1053D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100929718; called by muse, mutect2, varscan2
- IRX1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100116798; called by muse, mutect2
- IRX2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV100121901, COSV57412154; called by muse, mutect2
- ITGAL | c.569C>A p.S190* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100776345, COSV63319994; called by muse, mutect2, varscan2
- ITGAV | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99655623; called by muse, mutect2, varscan2
- ITGB3 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.03); catalogued as rs1238963431, COSV101457671; called by muse, mutect2, varscan2
- ITM2A | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377718732, COSV100964492; called by muse, mutect2, varscan2
- ITPK1 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs1264197965, COSV99968943; called by muse, mutect2, varscan2
- JCAD | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1446107161, COSV64758126; called by muse, mutect2, varscan2
- JMJD6 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57974127; called by muse, mutect2, varscan2
- JPH3 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99413973; called by muse, mutect2
- KATNIP | c.3638A>T p.Q1213L | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV99851956; called by muse, mutect2, varscan2
- KCNA2 | c.984G>T p.L328F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1424954493, COSV100316115; called by muse, mutect2, varscan2
- KCNA5 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV52906292; called by muse, varscan2
- KCNA5 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99364197; called by muse, varscan2
- KCND2 | c.780T>A p.S260R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100478425; called by muse, mutect2, varscan2
- KCND2 | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.361); catalogued as COSV100478431; called by muse, mutect2, varscan2
- KCNH1 | c.2747C>A p.P916H (on ENST00000271751 / NM_172362.3; = p.P889H on NM_002238.4) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV99659092; called by muse, mutect2, varscan2
- KCNH1 | c.1222G>T p.E408* (on ENST00000271751 / NM_172362.3; = p.E381* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 72/101 reads (71%) | catalogued as COSV55069391, COSV55081940; called by muse, mutect2, varscan2
- KCNH2 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1198513528, COSV100061010; called by muse, mutect2, varscan2
- KCNH6 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1213260073, COSV100121250; called by muse, mutect2, varscan2
- KCNH8 | c.2613C>G p.N871K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100111003; called by muse, mutect2, varscan2
- KCNJ10 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 94/155 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100927958; called by muse, mutect2, varscan2
- KCNK13 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965920; called by muse, mutect2, varscan2
- KCNK2 | c.915C>A p.S305R (on ENST00000444842 / NM_001017425.3; = p.S290R on NM_014217.4) | Missense Mutation (SNP) | VAF 139/212 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101222328; called by muse, mutect2, varscan2
- KCNMA1 | c.3560C>A p.A1187D (on ENST00000286628 / NM_001161352.2; = p.A1129D on NM_002247.4) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV99699527; called by muse, mutect2, varscan2
- KCNMA1 | c.1460G>C p.C487S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99699536; called by muse, mutect2, varscan2
- KCNT2 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV99656616; called by muse, mutect2, varscan2
- KCTD3 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99379715; called by muse, mutect2, varscan2
- KDM6B | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs1213781581, COSV99642228; called by muse, mutect2, varscan2
- KIAA1549L | c.4626C>A p.S1542R (on ENST00000321505; = p.S1839R on NM_012194.3) | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100382352; called by muse, mutect2, varscan2
- KIAA1755 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV54076081; called by muse, mutect2, varscan2
- KIF17 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99929714; called by muse, mutect2, varscan2
- KIF5A | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99673561; called by muse, mutect2, varscan2
- KIF5B | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs533600588, COSV100192353; called by muse, mutect2, varscan2
- KIR3DL1 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs542355320, COSV58494871; called by muse, mutect2, varscan2
- KIR3DX1 | n.42-2A>T | Splice Site (SNP) | VAF 21/82 reads (26%) | catalogued as rs1456586536, COSV99683640; called by muse, mutect2
- KLHL8 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99911553, COSV99911573; called by muse, mutect2, varscan2
- KLK6 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037840; called by muse, mutect2, varscan2
- KRBOX4 | c.398G>A p.S133N (on ENST00000344302 / NM_001129898.2; = p.S128N on NM_017776.2) | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99994369; called by muse, mutect2, varscan2
- KRT25 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100380078; called by muse, mutect2, varscan2
- KRT3 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.115); catalogued as COSV100527312; called by muse, mutect2, varscan2
- KRT36 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 59/107 reads (55%) | catalogued as COSV100057729, COSV60203980; called by muse, mutect2, varscan2
- KRTAP19-1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.155); catalogued as COSV101185867; called by muse, mutect2, varscan2
- KRTAP19-1 | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV101185871; called by muse, mutect2, varscan2
- KRTAP6-1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | PolyPhen possibly damaging (0.884); catalogued as COSV100228836; called by muse, mutect2, varscan2
- KY | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.346); catalogued as rs1305528138, COSV101415035; called by muse, mutect2, varscan2
- LAMA4 | c.2849C>A p.P950Q (on ENST00000230538 / NM_001105206.3; = p.P943Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as CM073173, COSV100038321, COSV100039392; called by muse, mutect2, varscan2
- LAMB1 | c.2761G>T p.D921Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99741628; called by muse, mutect2, varscan2
- LAMB4 | c.2996A>G p.Q999R | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99225515; called by muse, varscan2
- LAMB4 | c.1883C>A p.T628N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV99225521; called by muse, mutect2, varscan2
- LAMC2 | c.1390T>A p.C464S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99917938; called by muse, mutect2, varscan2
- LARP4B | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV100295649; called by muse, mutect2, varscan2
- LCOR | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1322205855, COSV99617178; called by muse, mutect2, varscan2
- LCT | c.3444G>T p.Q1148H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99930381; called by muse, mutect2, varscan2
- LCT | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930383; called by muse, mutect2, varscan2
- LCT | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV99919371; called by muse, mutect2, varscan2
- LEFTY2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs1287624420, COSV100832658; called by muse, mutect2, varscan2
- LGMN | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100605992; called by muse, varscan2
- LHFPL3 | c.440A>C p.D147A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.088); catalogued as COSV101308853; called by muse, mutect2, varscan2
- LILRA5 | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100007090; called by muse, mutect2, varscan2
- LILRB1 | c.628G>T p.A210S (on ENST00000427581; = p.A174S on NM_006669.6) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV100207851; called by muse, mutect2, varscan2
- LILRB5 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.204); catalogued as COSV100300790; called by muse, mutect2, varscan2
- LIN7C | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV99536313; called by muse, mutect2, varscan2
- LINGO2 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100431187, COSV58065216; called by muse, mutect2, varscan2
- LITAF | c.375G>T p.L125= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs1465028412, COSV100243237; called by muse, mutect2, varscan2
- LIX1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV99172969; called by muse, mutect2, varscan2
- LPA | c.5285G>A p.W1762* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV60300642; called by muse, mutect2, varscan2
- LPP | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100448284; called by muse, mutect2, varscan2
- LRATD2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1454199500, COSV100513662; called by muse, mutect2, varscan2
- LRGUK | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs763281518, COSV99604658; called by muse, mutect2, varscan2
- LRP12 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99408323; called by muse, mutect2, varscan2
- LRP1B | c.11454T>A p.C3818* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV101260570; called by muse, mutect2, varscan2
- LRP1B | c.9815T>A p.V3272D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101260573; called by muse, mutect2, varscan2
- LRP1B | c.1183G>T p.G395* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV101260574; called by muse, mutect2, varscan2
- LRP2 | c.7454A>T p.Y2485F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99790184; called by muse, mutect2, varscan2
- LRP2 | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790186; called by muse, mutect2
- LRRC32 | c.1748C>G p.A583G | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99477289; called by muse, mutect2, varscan2
- LRRC7 | c.2426G>T p.G809V (on ENST00000651989 / NM_001370785.2; = p.G776V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV99225079, COSV99229611; called by muse, mutect2
- LRRTM1 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs745448568, COSV99703132; called by muse, mutect2, varscan2
- LRRTM3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100791906; called by muse, mutect2
- LRRTM4 | c.645C>G p.N215K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297728; called by muse, mutect2, varscan2
- LSS | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs1401379757, COSV100711044; called by muse, mutect2, varscan2
- LTA | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV101403262; called by muse, mutect2, varscan2
- LTB | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs773880151, COSV53001780, COSV99279204; called by muse, mutect2, varscan2
- LTBP2 | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752483332, COSV100000917; called by muse, mutect2, varscan2
- LYG1 | c.132C>A p.H44Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100415802, COSV100415814; called by muse, mutect2, varscan2
- LZTR1 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99302275; called by muse, mutect2, varscan2
- MAB21L1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as rs761388842, COSV100083969; called by muse, mutect2, varscan2
- MAB21L4 | c.1301G>T p.S434I (on ENST00000388934 / NM_001085437.3; = p.S266I on NM_024861.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs746355182, COSV56743336; called by muse, mutect2, varscan2
- MACC1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778129711, COSV100256259; called by muse, mutect2, varscan2
- MACF1 | c.5812G>T p.D1938Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99246700; called by muse, mutect2
- MACF1 | c.12304G>T p.E4102* (on ENST00000372915; = p.E2035* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | catalogued as COSV99246701; called by muse, mutect2, varscan2
- MACF1 | c.21230T>C p.L7077S (on ENST00000372915; = p.L5122S on NM_012090.5) | Missense Mutation (SNP) | VAF 80/138 reads (58%) | catalogued as COSV99246709; called by muse, mutect2, varscan2
- MACROD1 | c.517+1G>T p.X173_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99736060; called by muse, mutect2, varscan2
- MACROD1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139146238, COSV99735140; called by muse, mutect2, varscan2
- MAG | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62700841, COSV62702443; called by muse, mutect2, varscan2
- MAG | c.1273C>G p.R425G | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs1366805488, COSV100728046, COSV62699261; called by muse, mutect2, varscan2
- MAGEA11 | c.102C>A p.S34R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100290686; called by muse, mutect2, varscan2
- MAGEA11 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV100290688; called by muse, mutect2, varscan2
- MAGEA12 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 61/68 reads (90%) | catalogued as COSV100757043; called by muse, mutect2, varscan2
- MAGEC1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99596478; called by muse, mutect2, varscan2
- MAGEE1 | c.2326G>T p.G776C | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100819526; called by muse, mutect2, varscan2
- MAGI1 | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100443042; called by muse, mutect2, varscan2
- MAP1B | c.6714T>A p.D2238E | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV99702920; called by muse, mutect2, varscan2
- MAP3K9 | c.2986C>A p.R996S (on ENST00000554752 / NM_001284230.1; = p.R1010S on NM_033141.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101173755, COSV67120476; called by muse, mutect2, varscan2
- MAP4K1 | c.2495-1G>A p.X832_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100616913; called by muse, mutect2, varscan2
- MARK1 | c.1933A>T p.R645* | Nonsense Mutation (SNP) | VAF 84/113 reads (74%) | catalogued as COSV100857548; called by muse, mutect2, varscan2
- MASTL | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668964, COSV60912860; called by muse, mutect2, varscan2
- MAT1A | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs757190246, COSV100944490; called by muse, mutect2, varscan2
- MBL2 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 31/176 reads (18%) | catalogued as rs1398071537, COSV100906407; called by muse, mutect2, varscan2
- MCM10 | c.1748G>C p.R583P (on ENST00000484800 / NM_182751.3; = p.R582P on NM_018518.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101098443; called by muse, mutect2
- MDN1 | c.6934A>G p.I2312V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV101021809; called by muse, mutect2, varscan2
- MED12 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100379840, COSV61337091; called by muse, mutect2, varscan2
- MEGF10 | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99175606; called by muse, mutect2, varscan2
- MEGF10 | c.1702T>A p.C568S | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99175615; called by muse, mutect2, varscan2
- MEGF6 | c.347A>T p.Q116L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs1480293854, COSV100742333; called by muse, mutect2, varscan2
- MEIS1 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99715772; called by muse, mutect2, varscan2
- MEIS1 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715773; called by muse, mutect2, varscan2
- METTL15 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100328762; called by muse, mutect2, varscan2
- METTL2A | c.587T>A p.F196Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV100274314; called by muse, mutect2, varscan2
- MFN1 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99764694; called by muse, mutect2, varscan2
- MFSD6 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV55623450, COSV99855393; called by muse, mutect2, varscan2
- MGAM | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101516545; called by muse, mutect2, varscan2
- MIA2 | c.1541G>T p.R514I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54502880; called by muse, mutect2, varscan2
- MIGA1 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100889811; called by muse, mutect2, varscan2
- MINDY4 | c.1971+1G>T p.X657_splice | Splice Site (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99519222; called by muse, mutect2, varscan2
- MLEC | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1462116623, COSV57329487; called by muse, mutect2, varscan2
- MMP10 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666700; called by muse, mutect2, varscan2
- MMP13 | c.401T>A p.V134D | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99506832; called by muse, mutect2, varscan2
- MON1B | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1383447879, COSV99941847; called by muse, mutect2, varscan2
- MORC4 | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV99717591; called by muse, mutect2, varscan2
- MOS | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100323023; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3061G>T p.V1021F | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs752545389, COSV100186366, COSV100187187; called by muse, mutect2, varscan2
- MRC2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100316745; called by muse, mutect2, varscan2
- MRC2 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365527481, COSV100316747; called by muse, mutect2, varscan2
- MRC2 | c.1082A>C p.K361T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316748; called by muse, mutect2, varscan2
- MROH8 | c.1989G>T p.K663N | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.113); catalogued as COSV99457891; called by muse, mutect2, varscan2
- MS4A13 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981207; called by muse, mutect2, varscan2
- MS4A4A | c.296del p.V99Gfs*11 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | catalogued as COSV100557806; called by mutect2, pindel, varscan2
- MTBP | c.1931A>T p.Q644L | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1344122430, COSV100012551; called by muse, mutect2, varscan2
- MTM1 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100080668; called by muse, mutect2, varscan2
- MTNR1A | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100208324; called by muse, mutect2, varscan2
- MTUS2 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV101462360; called by muse, mutect2, varscan2
- MUC16 | c.30935C>A p.P10312H | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV101201517; called by muse, mutect2, varscan2
- MUC16 | c.8864C>A p.S2955* | Nonsense Mutation (SNP) | VAF 44/54 reads (81%) | catalogued as COSV101201519; called by muse, mutect2, varscan2
- MYBPC2 | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV100732021; called by muse, mutect2, varscan2
- MYCBP2 | c.2471A>C p.K824T (on ENST00000357337; = p.K862T on NM_015057.5) | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100631800; called by muse, mutect2, varscan2
- MYCBPAP | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100089049; called by muse, mutect2, varscan2
- MYEOV | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.441); catalogued as COSV100456736; called by muse, mutect2, varscan2
- MYF5 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs757659254, COSV57355707, COSV57357088; called by muse, mutect2, varscan2
- MYH2 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99820916; called by muse, mutect2, varscan2
- MYH3 | c.4904G>T p.R1635L | Missense Mutation (SNP) | VAF 104/176 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV56866338, COSV99878836; called by muse, mutect2, varscan2
- MYH4 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as COSV99702185; called by muse, mutect2, varscan2
- MYLK | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100659586; called by muse, mutect2, varscan2
- MYLK | c.2075C>A p.T692K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.042); catalogued as COSV100659587; called by muse, mutect2, varscan2
- MYO15A | c.9229G>T p.A3077S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99234360; called by muse, mutect2, varscan2
- MYO18A | c.3340G>T p.D1114Y | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62862558; called by muse, mutect2, varscan2
- MYO3A | c.1972A>G p.R658G | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56352344; called by muse, varscan2
- MYO3A | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99781456; called by muse, varscan2
- MYO7B | c.4745C>A p.S1582* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101268380; called by muse, mutect2, varscan2
- MYOC | c.235A>T p.S79C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99231713; called by muse, mutect2, varscan2
- MYOF | c.2589G>T p.M863I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV100826103; called by muse, mutect2, varscan2
- MYT1L | c.1661C>A p.T554K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV67710530, COSV67728605; called by muse, varscan2
- NAA11 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727539; called by muse, mutect2, varscan2
- NAA35 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100863445; called by muse, mutect2, varscan2
- NAALADL2 | c.1230T>A p.N410K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1234185222; called by mutect2, varscan2
- NAALADL2 | c.1232_1233insG p.N411Kfs*2 | Frame Shift Ins (INS) | VAF 11/17 reads (65%) | catalogued as COSV101380484; called by mutect2, varscan2
- NAMPT | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55994150, COSV99748282; called by muse, mutect2, varscan2
- NAMPT | c.843T>G p.Y281* | Nonsense Mutation (SNP) | VAF 53/130 reads (41%) | catalogued as COSV99748285; called by muse, mutect2, varscan2
- NAP1L2 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100999228, COSV65172547; called by muse, mutect2, varscan2
- NAT16 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100296398; called by muse, mutect2, varscan2
- NAV3 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1260108374, COSV57078764, COSV99895352; called by muse, mutect2, varscan2
- NAV3 | c.1757G>T p.R586M | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99895356; called by muse, mutect2, varscan2
- NCBP3 | c.1627+1G>T p.X543_splice | Splice Site (SNP) | VAF 26/101 reads (26%) | catalogued as rs1197158256, COSV99339706; called by muse, mutect2, varscan2
- NCF4 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV99957531; called by muse, mutect2, varscan2
- NCOA4 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 138/236 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554922902; called by muse, mutect2, varscan2
- NDRG1 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100106433; called by muse, mutect2, varscan2
- NDRG3 | c.802G>T p.E268* (on ENST00000349004 / NM_032013.4; = p.E256* on NM_022477.4) | Nonsense Mutation (SNP) | VAF 78/116 reads (67%) | catalogued as COSV100675457; called by muse, mutect2, varscan2
- NDST4 | c.1628G>C p.W543S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV52136920, COSV99997800; called by muse, mutect2, varscan2
- NEMP1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV100272292; called by muse, mutect2, varscan2
- NIBAN1 | c.1065G>T p.M355I | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100836612; called by muse, mutect2, varscan2
- NID2 | c.1277G>C p.G426A | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99355900, COSV99357220; called by muse, mutect2, varscan2
- NINL | c.1337G>T p.R446M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54000679; called by muse, mutect2, varscan2
- NIPBL | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99242551; called by muse, mutect2
- NKPD1 | c.2455T>A p.C819S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as rs1402121427, COSV99675035; called by muse, mutect2, varscan2
- NLGN1 | c.2360C>G p.T787S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.076); catalogued as COSV64342087; called by muse, mutect2, varscan2
- NLK | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.182); catalogued as COSV101311355; called by muse, mutect2
- NLRP13 | c.1658C>A p.P553H | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs1339309820, COSV100738505; called by muse, mutect2, varscan2
- NLRP5 | c.1095T>A p.D365E | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.735); catalogued as rs1158409800, COSV101173868; called by muse, mutect2, varscan2
- NLRP7 | c.693G>T p.W231C | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as CM126043, COSV100053342, COSV60173131; called by muse, mutect2, varscan2
- NLRP8 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs569527827, COSV99405920; called by muse, mutect2, varscan2
- NOBOX | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as rs1465960089, COSV99779680; called by muse, mutect2, varscan2
- NOS1 | c.1901C>G p.A634G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100501370; called by muse, mutect2, varscan2
- NOS1AP | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 120/162 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100723606; called by muse, mutect2, varscan2
- NOS3 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99872132; called by muse, mutect2, varscan2
- NPAS3 | c.1046+1G>C p.X349_splice (on ENST00000356141 / NM_001164749.2; = p.X317_splice on NM_022123.3) | Splice Site (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100640649; called by muse, mutect2, varscan2
- NPAS4 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.063); catalogued as COSV100214973; called by muse, mutect2, varscan2
- NPAS4 | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.95); catalogued as COSV100215247; called by muse, mutect2, varscan2
- NPHS1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs752311438, COSV100800252; called by muse, varscan2
- NPR1 | c.2200C>A p.L734M | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV100902077; called by muse, mutect2, varscan2
- NR1H4 | c.37T>A p.L13I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100321432; called by muse, mutect2, varscan2
- NR2C2 | c.860T>C p.L287P (on ENST00000393102; = p.L306P on NM_003298.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100038856; called by muse, mutect2, varscan2
- NRBF2 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV99515233; called by muse, mutect2
- NRCAM | c.1770T>A p.S590R (on ENST00000379028 / NM_001371124.1; = p.S584R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100695444; called by muse, mutect2, varscan2
- NRDC | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV100703835; called by muse, mutect2, varscan2
- NRROS | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as rs1381266352, COSV100145608; called by muse, mutect2, varscan2
- NRXN2 | c.3713C>A p.T1238N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99635678; called by muse, mutect2, varscan2
- NTN4 | c.1378G>T p.G460* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs750508188, COSV100643836, COSV100643866; called by muse, mutect2, varscan2
- NTNG2 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100647730; called by muse, mutect2
- NUDT18 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV99249261; called by muse, mutect2, varscan2
- NUP133 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99773446; called by muse, mutect2, varscan2
- NUTM2G | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as COSV100672963; called by muse, mutect2, varscan2
- NXF1 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99586435; called by muse, mutect2, varscan2
- OCA2 | c.2467G>T p.V823F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100668627; called by muse, mutect2, varscan2
- OCM | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs745567019, COSV54194553; called by muse, mutect2, varscan2
- OMA1 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100678384; called by muse, mutect2, varscan2
- OMA1 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100678387; called by muse, mutect2, varscan2
- OPLAH | c.3643G>T p.G1215C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101085294; called by muse, mutect2
- OPRM1 | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100386251, COSV57825279; called by muse, mutect2, varscan2
- OR10C1 | c.458G>T p.G153V (on ENST00000622521; = p.G151V on NM_013941.3) | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101010891; called by muse, mutect2, varscan2
- OR13C4 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52927901; called by muse, mutect2, varscan2
- OR14C36 | c.853C>G p.P285A | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100507647, COSV58601906; called by muse, mutect2, varscan2
- OR14K1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.902); catalogued as COSV99315460; called by muse, mutect2
- OR1S1 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV100515487; called by muse, mutect2, varscan2
- OR2B11 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100276618; called by muse, mutect2, varscan2
- OR2C3 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100825789; called by muse, mutect2, varscan2
- OR2G6 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs773244859, COSV100598311, COSV58573623; called by muse, mutect2, varscan2
- OR2L13 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV63558072, COSV63561266; called by muse, mutect2, varscan2
- OR2M3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV71759306; called by muse, mutect2, varscan2
- OR2T1 | c.356A>C p.Y119S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100822353, COSV63542881; called by muse, mutect2, varscan2
- OR4A5 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100157291; called by muse, mutect2, varscan2
- OR4S2 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1484525917, COSV100412705, COSV100412799; called by muse, mutect2, varscan2
- OR4X2 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 55/73 reads (75%) | catalogued as rs774379503, COSV100183340; called by muse, mutect2, varscan2
- OR51A7 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV100834757; called by muse, mutect2, varscan2
- OR51M1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60784494; called by muse, mutect2, varscan2
- OR52R1 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs757095781, COSV100617805; called by muse, mutect2, varscan2
1,016 further variants in this file (534 protein-altering or splice-affecting, 427 silent, 55 other) are not listed here.
